Somatic mutation profile of tumor specimen ALCH-B1YT-TTP1-A (aliquot ALCH-B1YT-TTP1-A-2-0-D-A76I-36) from ALCHEMIST case ALCH-B1YT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.3 years (19,849 days).
Specimen ALCH-B1YT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 295fd0bf-7a68-48b1-b6d6-98153c2bfb2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1YT-NB1-A (Blood Derived Normal), aliquot ALCH-B1YT-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13e97971-e4b6-484a-be95-3d101fb5fd3e

The open-access MAF lists 42 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 9, Splice Site 2, Intron 2, 3'Flank 1, Splice Region 1, 3'UTR 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH4 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 28/756 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1485834330, COSV64667597; called by muse, mutect2
- CERT1 | c.754G>C p.E252Q (on ENST00000405807 / NM_001130105.1; = p.E124Q on NM_005713.3) | Missense Mutation (SNP) | VAF 13/348 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs995534431; ClinVar: uncertain significance; called by muse, mutect2
- CHP1 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs867542118, COSV58158622; called by muse, mutect2
- FCRL2 | c.1004A>T p.Y335F | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as rs764330110; called by muse, mutect2
- GALE | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 34/840 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs1412310127; called by muse, mutect2
- GJC2 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM125681; called by muse, mutect2
- KLHL3 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 33/534 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769995865, COSV59055050; called by muse, mutect2
- MASP1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 22/586 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV51459001, COSV51460493; called by muse, mutect2
- NSD1 | c.5255A>G p.K1752R | Missense Mutation (SNP) | VAF 28/602 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.855); catalogued as rs754939355; called by muse, mutect2
- ZNF404 | c.81G>C p.Q27H | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60987979; called by muse, mutect2
- ACSM2A | c.1630-2A>C p.X544_splice (on ENST00000219054; = p.X465_splice on NM_001308169.2) | Splice Site (SNP) | VAF 11/181 reads (6%) | called by muse, mutect2
- ACSS3 | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2
- ARFGEF1 | c.2442A>G p.G814= | Splice Region (SNP) | VAF 9/208 reads (4%) | called by muse, mutect2
- DEPDC5 | c.1832C>T p.T611M | Missense Mutation (SNP) | VAF 24/567 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- FDXACB1 | c.1222C>G p.L408V | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2
- GREB1L | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 11/182 reads (6%) | called by muse, mutect2
- HPSE2 | c.1206-1G>C p.X402_splice | Splice Site (SNP) | VAF 16/514 reads (3%) | called by muse, mutect2
- IGLV3-27 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 26/602 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2
- KLHL17 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 23/412 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- KSR2 | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- MYO15B | c.2500G>C p.E834Q | Missense Mutation (SNP) | VAF 16/475 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.273); called by muse, mutect2
- MYO19 | c.2656G>C p.V886L (on ENST00000614623 / NM_001163735.1; = p.V686L on NM_025109.5) | Missense Mutation (SNP) | VAF 28/598 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- OGG1 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- RASSF10 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.031); called by muse, mutect2
- RNGTT | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- RPL13A | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 15/450 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- XK | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 16/483 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); called by muse, mutect2
- ZC3H14 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 16/449 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2
- CENATAC | c.909C>G p.V303= | Silent (SNP) | VAF 8/233 reads (3%) | catalogued as rs1377628226; called by muse, mutect2
- DDI1 | c.939C>T p.F313= | Silent (SNP) | VAF 13/346 reads (4%) | catalogued as COSV56389762; called by muse, mutect2
- IGKV1D-17 | c.45C>T p.L15= | Silent (SNP) | VAF 13/396 reads (3%) | called by muse, mutect2
- INSL6 | c.165C>T p.F55= | Silent (SNP) | VAF 34/776 reads (4%) | catalogued as rs1253150884, COSV67562507; called by muse, mutect2
- PCDHB11 | c.2217G>C p.V739= | Silent (SNP) | VAF 18/650 reads (3%) | catalogued as COSV61310181; called by muse, mutect2
- POMGNT2 | c.1134G>A p.K378= | Silent (SNP) | VAF 20/686 reads (3%) | called by muse, mutect2
- SLC6A19 | c.219G>A p.P73= | Silent (SNP) | VAF 76/698 reads (11%) | catalogued as rs776566109, COSV58669498; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYNRG | c.912G>A p.K304= | Silent (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- WIPF1 | c.414G>A p.A138= | Silent (SNP) | VAF 39/747 reads (5%) | catalogued as rs758832978, COSV55814262; called by muse, mutect2
- ATP2A2 | c.545-17T>C | Intron (SNP) | VAF 22/492 reads (4%) | called by muse, mutect2
- CPNE7 | c.1764+299G>A | Intron (SNP) | VAF 20/408 reads (5%) | catalogued as rs760626323; called by muse, mutect2
- DOCK1 | c.*87T>A | 3'UTR (SNP) | VAF 9/165 reads (5%) | called by muse, mutect2
- FBXO30 | chr6:145791561 C>G | 3'Flank (SNP) | VAF 5/105 reads (5%) | called by muse, mutect2
- MIR155 | chr21:25573957 G>A | 5'Flank (SNP) | VAF 15/426 reads (4%) | catalogued as rs1389961153; called by muse, mutect2
